Surgical pathology report (de-identified scan), TCGA case TCGA-Q3-A5QY, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site University of Oklahoma HSC, specimen TCGA-Q3-A5QY-01A (Primary Tumor).

[page 1 of 3]
Specimen Inquiry

PATIENT: ACCT #: LOC: U#:
AGE/SX:

REG DR:

SPEC #: Obtained:

CLINICAL HISTORY:

PANCREATIC MASS; TISSUE #1 MARKED AS FOLLOWS: LONG STITCH - PANCREATIC MARGIN, SHORT STITCH - RETROPERITONEAL MARGIN, BLUE STITCH - BILE DUCT

SPECIMEN/PROCEDURE:

1. PANCREAS - WHIPPLE

IMPRESSION:

DUODENUM, PANCREAS AND COMMON BILE DUCT, WHIPPLE PROCEDURE WITH EXTENDED DUODENECTOMY:

- . Ductal adenocarcinoma, moderately differentiated.
- . Metastatic carcinoma present in four of eighteen lymph nodes.
- . Adenocarcinoma invades muscularis propria of duodenum.
- . See tumor checklist.

PANCREAS (EXOCRINE): RESECTION CASE SUMMARY

SPECIMEN

Head of pancreas
Duodenum
Common bile duct

ICD-O-3
Adenocarcinoma, duct NDS
8500.3
Site: Head of pancreas
025.0
JW 4/12/13

PROCEDURE

Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy

TUMOR SITE

Pancreatic head

TUMOR SIZE

Greatest dimension: 2.7 cm
Additional dimensions: 2.2 x 2.0 cm

HISTOLOGIC TYPE

Ductal adenocarcinoma

HISTOLOGIC GRADE (DUCTAL CARCINOMA ONLY)

G2: Moderately differentiated

MICROSCOPIC TUMOR EXTENSION

Tumor invades duodenal wall
Tumor invades other peripancreatic soft tissue (specify): Inferior

MARGINS

Margins uninvolved by tumor
Distance of tumor from closest margin: 5 mm
Specify margin (if possible): Retroperitoneal

[page 2 of 3]
IMPRESSION: (continued)**TREATMENT EFFECT (APPLICABLE TO CARCINOMAS TREATED WITH NEOADJUVANT THERAPY)**

No known prior treatment

LYMPH-VASCULAR INVASION

Not identified

PERINEURAL INVASION

Present

PATHOLOGIC STAGING (pTNM)**PRIMARY TUMOR (pT)**

pT3: Tumor extends beyond the pancreas but without involvement of the celiac axis or the superior mesenteric artery

REGIONAL LYMPH NODES (pN)

pN1: Regional lymph node metastasis

Specify: Number of lymph nodes examined: 18
Number of lymph nodes involved: 4**DISTANT METASTASIS (pM)**

Not applicable

ADDITIONAL PATHOLOGIC FINDINGSPancreatic intraepithelial neoplasia (highest grade: PanIN):
Chronic pancreatitis
Other (specify): Fat necrosis**ANCILLARY STUDIES**

Not performed

CLINICAL HISTORY

Not specified

Pathologic TNM (AJCC 7th Edition): pT3 N1

GROSS DESCRIPTION:

1. Received fresh, labeled with the patient's name and "Whipple," is a 250 g specimen consisting of duodenum (21 cm in length by 7 cm in circumference by 0.6 cm in wall thickness) and pancreatic head (8 x 5 x 4 cm). There is a firm, tan-white poorly circumscribed tumor mass in the head of the pancreas (2.7 x 2.2 x 2.0 cm) which appears to be centered around the pancreatic duct, constricting it. The bile duct is patent and 0.4 cm in diameter. The tumor is 0.5 cm from the ampulla of Vater and does not grossly involve the duodenal muscularis or mucosa. The tumor is 1.4 cm from the distal pancreatic resection margin, which is grossly free of tumor. The lateral margins are composed of golden adipose tissue ranging in thickness from 0.5-2.5 cm and are grossly free of tumor. The remainder of the pancreatic parenchyma is firm and nodular. The cystic duct remnant is 2 cm in length by 0.8 cm in diameter. The duodenal mucosa is tan to slightly dusky with appropriate folding. Seven lymph nodes are present adjacent to the pancreas (1 superior, 6 inferior), the largest measuring 0.7 cm.

[page 3 of 3]
GROSS DESCRIPTION: (continued)

Ink code: Blue-parenchymal margin; black-retroperitoneal margin; red-vascular groove

CASSETTE SUMMARY:

CASSETTE 1A: Ampulla of Vater
CASSETTE 1B-1D: Pancreatic resection margin, with relationship to tumor, parallel sections
CASSETTE 1E: Common bile duct margin, en face
CASSETTE 1G-1J: Retroperitoneal margin, serially sectioned
CASSETTE 1K: Proximal duodenal margin
CASSETTE 1L: Distal duodenal margin
CASSETTE 1M: Tumor, showing relationship to surrounding tissue
CASSETTE 1N: Tumor, showing relationship to vascular groove
CASSETTE 1P: Tumor, showing relationship to duodenum
CASSETTE 1Q: Tumor, showing relationship to duodenal
CASSETTE 1R: 3 lymph nodes bisected, un-inked from superior, blue and black inked from inferior
CASSETTE 1S: 2 inferior lymph nodes, one bisected, the other inked blue
CASSETTE 1U: 2 inferior lymph nodes, one inked black

Entere.

COPIES TO:**CPT Codes:**

PANCREAS PART/TTL RESECTION/88309, SMALL BOWEL RESECTION BENIGN/88307

ICD9 Codes:

157.1

I have personally reviewed the material
(specimen/slide) and approve this final report.

Electronically Signed by:

** END OF REPORT **

Criteria	W 11/31/13	Yes	No
IHPAA Discrepancy			

Source: NCI Genomic Data Commons file bcd0c224-1d48-41ea-9fbc-cb70e8baebfa (TCGA-Q3-A5QY.37299156-9A64-43F6-A4E1-AC398483ADF4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).